Somatic mutation profile of tumor specimen TCGA-W9-A837-01A (aliquot TCGA-W9-A837-01A-11D-A36O-08) from TCGA case TCGA-W9-A837, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2.
Specimen TCGA-W9-A837-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb323fd2-bf97-49fe-bf08-0dbc41a99962.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-W9-A837-10A (Blood Derived Normal), aliquot TCGA-W9-A837-10A-01D-A367-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a9d1f27f-2cf0-4349-99ac-5933a1b7ce09

The open-access MAF lists 30 somatic variants for this specimen: 21 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 17, Silent 9, Frame Shift Del 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 39/97 reads (40%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- NIPBL | c.772-1G>A p.X258_splice | Splice Site (SNP) | VAF 9/56 reads (16%) | catalogued as rs587784049, COSV99240475; ClinVar: pathogenic; called by muse, mutect2
- ADGRD1 | c.832C>A p.P278T | Missense Mutation (SNP) | VAF 16/295 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1450456108, COSV99895320; called by muse, mutect2
- DNAH9 | c.7637A>G p.D2546G | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1251067730, COSV99305746; called by muse, mutect2
- FAT2 | c.4142G>C p.W1381S | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99942764, COSV99944079; called by muse, mutect2, varscan2
- GINM1 | c.442G>T p.D148Y | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV100805319; called by muse, mutect2, varscan2
- LAMA4 | c.1219G>A p.E407K (on ENST00000230538 / NM_001105206.3; = p.E400K on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 79/187 reads (42%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as COSV100038320; called by muse, mutect2, varscan2
- NIPBL | c.1741C>T p.L581F | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.015); catalogued as COSV99240476; called by muse, mutect2
- OR56A4 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.03); catalogued as COSV100417558; called by muse, mutect2, varscan2
- PLEKHG4 | c.1264G>A p.D422N | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as COSV100846497; called by mutect2, varscan2
- RTF1 | c.1646T>A p.L549Q | Missense Mutation (SNP) | VAF 15/151 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101047815; called by muse, mutect2, varscan2
- SLC13A4 | c.1044G>C p.K348N | Missense Mutation (SNP) | VAF 6/139 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.828); catalogued as COSV100818869; called by muse, mutect2
- SPATA31E1 | c.985C>T p.R329W | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as rs770623783, COSV57790807; called by muse, mutect2, varscan2
- TELO2 | c.577G>A p.V193I | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs781236535, COSV99248299; called by muse, mutect2, varscan2
- TMEM220 | c.280G>C p.E94Q | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100541371; called by muse, mutect2
- TPSD1 | c.653G>A p.C218Y | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99273833; called by muse, mutect2, varscan2
- ZDBF2 | c.2443G>A p.V815I | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as COSV100984800; called by muse, mutect2
- CELA2A | c.661A>G p.N221D | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- CPEB4 | c.1954_1957del p.D652Nfs*62 | Frame Shift Del (DEL) | VAF 20/98 reads (20%) | called by pindel, varscan2
- DBI | c.132del p.M47Cfs*16 (on ENST00000355857 / NM_001079862.3; = p.M64Cfs*16 on NM_020548.8 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 10/41 reads (24%) | called by mutect2, pindel, varscan2
- SLC39A7 | c.280del p.H94Mfs*51 | Frame Shift Del (DEL) | VAF 27/79 reads (34%) | called by mutect2, pindel, varscan2
- AHNAK | c.1642C>T p.L548= | Silent (SNP) | VAF 8/193 reads (4%) | catalogued as COSV57208135; called by muse, mutect2
- CAT | c.441A>G p.G147= | Silent (SNP) | VAF 28/91 reads (31%) | catalogued as COSV99573227; called by muse, mutect2, varscan2
- CRTC1 | c.1806C>T p.I602= | Silent (SNP) | VAF 147/360 reads (41%) | catalogued as rs1479378151, COSV58718533; called by muse, mutect2, varscan2
- DENND3 | c.1953C>T p.G651= | Silent (SNP) | VAF 34/90 reads (38%) | catalogued as rs376076551; called by muse, mutect2, varscan2
- KLHDC8B | c.174A>G p.T58= | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as rs1382159075, COSV100234198; called by muse, mutect2
- OBSCN | c.11052C>T p.R3684= | Silent (SNP) | VAF 28/110 reads (25%) | catalogued as rs747549726, COSV52803658, COSV52811251; called by muse, mutect2, varscan2
- RBFOX1 | c.771G>A p.P257= | Silent (SNP) | VAF 3/41 reads (7%) | catalogued as rs916986800, COSV60959742; ClinVar: likely benign; called by muse, mutect2
- SNX6 | c.357A>G p.L119= (on ENST00000652385; = p.L107= on NM_152233.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/73 reads (10%) | catalogued as rs1247678267, COSV100751477; called by muse, mutect2
- UTP15 | c.603C>G p.L201= | Silent (SNP) | VAF 12/127 reads (9%) | catalogued as rs1309823320, COSV99707015; called by muse, mutect2
